Somatic mutation profile of tumor specimen TCGA-77-8144-01A (aliquot TCGA-77-8144-01A-11D-2244-08) from TCGA case TCGA-77-8144, project TCGA-LUSC (Lung Squamous Cell Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Upper lobe, lung; AJCC pathologic stage: Stage IB; Age at diagnosis: 70.6 years (25,796 days).
Specimen TCGA-77-8144-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) cb61a6f6-5aa0-4dc3-8f3f-a53596f925eb.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-77-8144-10A (Blood Derived Normal), aliquot TCGA-77-8144-10A-01D-2244-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/4c812b26-cd1c-46cd-bccb-ebd890f43dec

The open-access MAF lists 442 somatic variants for this specimen: 341 protein-altering or splice-affecting, 95 silent, 6 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 287, Silent 95, Nonsense Mutation 24, Frame Shift Del 11, Splice Site 11, Frame Shift Ins 6, RNA 4, Splice Region 2, Intron 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.880G>T p.E294* | Nonsense Mutation (SNP) | VAF 54/146 reads (37%) | hotspot (GDC flag); catalogued as rs1057520607, CM144128, COSV52689734, COSV52701760, COSV52773998, COSV53851434; ClinVar: pathogenic; called by muse, mutect2, varscan2
- TP53 | c.641A>G p.H214R | Missense Mutation (SNP) | VAF 27/66 reads (41%) | hotspot (GDC flag); SIFT deleterious (0.02); PolyPhen probably damaging (0.936); catalogued as rs1057519992, CM103210, COSV52670202, COSV52732998, COSV52834506, COSV52887765; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- A1CF | c.473A>C p.K158T | Missense Mutation (SNP) | VAF 70/165 reads (42%) | SIFT deleterious (0); PolyPhen possibly damaging (0.851); catalogued as COSV99255756; called by muse, mutect2, varscan2
- AADACL2 | c.1160T>C p.L387P | Missense Mutation (SNP) | VAF 17/64 reads (27%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.492); catalogued as COSV100735738; called by muse, mutect2, varscan2
- ABCA1 | c.2464A>T p.T822S | Missense Mutation (SNP) | VAF 66/219 reads (30%) | SIFT tolerated (0.29); PolyPhen benign (0.155); catalogued as COSV101036790; called by muse, mutect2, varscan2
- ABCC9 | c.3096+1G>T p.X1032_splice | Splice Site (SNP) | VAF 13/29 reads (45%) | catalogued as COSV99685338; called by muse, mutect2, varscan2
- ABCG4 | c.1732G>T p.V578L | Missense Mutation (SNP) | VAF 10/42 reads (24%) | SIFT tolerated (0.11); PolyPhen benign (0.17); catalogued as rs773823706, COSV100266673; called by muse, varscan2
- ABHD15 | c.1195C>T p.P399S | Missense Mutation (SNP) | VAF 22/44 reads (50%) | SIFT tolerated (0.64); PolyPhen benign (0.014); catalogued as COSV100212905; called by muse, mutect2, varscan2
- ABRAXAS2 | c.832G>T p.A278S | Missense Mutation (SNP) | VAF 22/56 reads (39%) | SIFT tolerated (0.39); PolyPhen benign (0); catalogued as COSV100044917; called by muse, mutect2, varscan2
- ACMSD | c.745C>A p.Q249K | Missense Mutation (SNP) | VAF 18/60 reads (30%) | SIFT tolerated (0.46); PolyPhen benign (0); catalogued as COSV99298951; called by muse, mutect2, varscan2
- ACSM4 | c.568C>A p.L190M | Missense Mutation (SNP) | VAF 7/29 reads (24%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.868); catalogued as COSV101257081; called by muse, mutect2
- ADAD1 | c.548C>A p.A183E | Missense Mutation (SNP) | VAF 10/37 reads (27%) | SIFT tolerated (0.33); PolyPhen benign (0); catalogued as rs367677453, COSV99635419; called by muse, mutect2, varscan2
- ADGRG3 | c.496C>T p.P166S | Missense Mutation (SNP) | VAF 53/136 reads (39%) | SIFT tolerated (0.15); PolyPhen benign (0.022); catalogued as COSV59652261; called by muse, mutect2, varscan2
- ADGRL3 | c.2681G>A p.R894H (on ENST00000506720 / NM_001322402.2; = p.R826H on NM_015236.6) | Missense Mutation (SNP) | VAF 8/19 reads (42%) | SIFT tolerated (0.07); PolyPhen benign (0.26); catalogued as rs372785017, COSV72230908; called by muse, mutect2, varscan2
- ADIG | c.215G>T p.G72V | Missense Mutation (SNP) | VAF 5/12 reads (42%) | SIFT deleterious (0); PolyPhen benign (0.161); catalogued as COSV100972536; called by muse, mutect2, varscan2
- ALG6 | c.760G>T p.E254* | Nonsense Mutation (SNP) | VAF 39/133 reads (29%) | catalogued as COSV99673112; called by muse, mutect2, varscan2
- ANKRD50 | c.3036G>T p.K1012N | Missense Mutation (SNP) | VAF 33/59 reads (56%) | SIFT tolerated (0.3); PolyPhen benign (0.055); catalogued as COSV101538921; called by muse, mutect2, varscan2
- ANKS4B | c.575G>A p.G192D | Missense Mutation (SNP) | VAF 27/74 reads (36%) | SIFT tolerated (0.56); PolyPhen benign (0.001); catalogued as COSV100289784; called by muse, mutect2, varscan2
- ANO1 | c.2483A>G p.H828R | Missense Mutation (SNP) | VAF 24/83 reads (29%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.829); catalogued as COSV100796978; called by muse, mutect2, varscan2
- AP5M1 | c.10C>T p.R4W | Missense Mutation (SNP) | VAF 38/135 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99841149; called by muse, mutect2, varscan2
- AQP10 | c.789G>T p.L263F | Missense Mutation (SNP) | VAF 35/104 reads (34%) | SIFT tolerated (0.51); PolyPhen benign (0.003); catalogued as COSV100270119; called by muse, mutect2, varscan2
- ARC | c.175C>A p.R59S | Missense Mutation (SNP) | VAF 10/25 reads (40%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.122); catalogued as COSV100751690; called by muse, mutect2, varscan2
- ARFGEF1 | c.4066G>A p.D1356N | Missense Mutation (SNP) | VAF 33/67 reads (49%) | SIFT tolerated (0.06); PolyPhen benign (0.027); catalogued as COSV99141897; called by muse, mutect2, varscan2
- ARID1B | c.1818G>T p.Q606H | Missense Mutation (SNP) | VAF 20/89 reads (22%) | SIFT tolerated, low confidence (0.07); PolyPhen possibly damaging (0.656); catalogued as COSV99268471, COSV99269137; called by muse, mutect2, varscan2
- ARRDC5 | c.844A>C p.S282R (on ENST00000381781; = p.S268R on NM_001080523.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 51/217 reads (24%) | SIFT tolerated (0.3); PolyPhen benign (0.003); catalogued as COSV101108144; called by muse, mutect2, varscan2
- ASPHD1 | c.1072G>A p.E358K | Missense Mutation (SNP) | VAF 35/121 reads (29%) | SIFT tolerated (0.11); PolyPhen benign (0.223); catalogued as rs373608288; called by muse, varscan2
- ATF7IP | c.424G>A p.G142R | Missense Mutation (SNP) | VAF 20/68 reads (29%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0.003); catalogued as rs767883210, COSV53776955, COSV99661480; called by muse, mutect2, varscan2
- ATP10B | c.2170G>T p.E724* | Nonsense Mutation (SNP) | VAF 7/70 reads (10%) | catalogued as COSV100514635; called by muse, mutect2, varscan2
- ATP10B | c.1993G>A p.D665N | Missense Mutation (SNP) | VAF 13/100 reads (13%) | SIFT tolerated (0.26); PolyPhen benign (0.018); catalogued as COSV100514636; called by muse, mutect2, varscan2
- ATP1B2 | c.757C>T p.P253S | Missense Mutation (SNP) | VAF 17/61 reads (28%) | SIFT tolerated (0.75); PolyPhen benign (0.062); catalogued as COSV100006874; called by muse, mutect2, varscan2
- ATP5F1A | c.61-1G>T p.X21_splice | Splice Site (SNP) | VAF 7/31 reads (23%) | catalogued as COSV99958847; called by muse, mutect2, varscan2
- AURKA | c.687T>A p.D229E | Missense Mutation (SNP) | VAF 6/35 reads (17%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.99); catalogued as COSV100452919; called by muse, mutect2, varscan2
- BAIAP2L1 | c.639+1G>A p.X213_splice | Splice Site (SNP) | VAF 45/246 reads (18%) | catalogued as COSV99133987; called by muse, mutect2, varscan2
- BAZ2A | c.3944C>G p.S1315C | Missense Mutation (SNP) | VAF 55/277 reads (20%) | SIFT tolerated (0.05); PolyPhen benign (0.001); catalogued as COSV99465451; called by muse, mutect2, varscan2
- BBS9 | c.2229G>T p.K743N (on ENST00000242067 / NM_001348036.1; = p.K703N on NM_014451.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 41/112 reads (37%) | SIFT tolerated (1); PolyPhen benign (0.009); catalogued as COSV99627394; called by muse, mutect2, varscan2
- BICD2 | c.2369T>C p.L790P | Missense Mutation (SNP) | VAF 13/75 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100794068; called by muse, mutect2, varscan2
- BOLL | c.461C>A p.S154* | Nonsense Mutation (SNP) | VAF 21/44 reads (48%) | catalogued as COSV56577227, COSV99986982; called by muse, mutect2, varscan2
- BYSL | c.121G>C p.G41R | Missense Mutation (SNP) | VAF 14/37 reads (38%) | SIFT tolerated (0.55); PolyPhen benign (0.007); catalogued as COSV99539806; called by muse, mutect2, varscan2
- CACNA2D1 | c.3064G>T p.G1022W (on ENST00000356253 / NM_001366867.1; = p.G1010W on NM_000722.4) | Missense Mutation (SNP) | VAF 12/26 reads (46%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.502); catalogued as COSV100666415; called by muse, mutect2, varscan2
- CAPN13 | c.769G>T p.E257* | Nonsense Mutation (SNP) | VAF 12/36 reads (33%) | catalogued as COSV99700058; called by muse, mutect2, varscan2
- CARS1 | c.1367A>T p.E456V | Missense Mutation (SNP) | VAF 8/28 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV99542472; called by mutect2, varscan2
- CASR | c.218C>T p.A73V | Missense Mutation (SNP) | VAF 31/75 reads (41%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.693); catalogued as COSV99948639; called by muse, mutect2, varscan2
- CCDC180 | c.4676G>A p.S1559N | Missense Mutation (SNP) | VAF 20/46 reads (43%) | SIFT tolerated (0.25); PolyPhen benign (0.33); catalogued as COSV100826640; called by muse, mutect2, varscan2
- CCDC39 | c.872T>C p.L291S | Missense Mutation (SNP) | VAF 13/29 reads (45%) | SIFT tolerated (0.21); PolyPhen benign (0.015); catalogued as COSV99868264; called by muse, mutect2, varscan2
- CCDC39 | c.515G>T p.R172M | Missense Mutation (SNP) | VAF 4/10 reads (40%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.906); catalogued as COSV99868268; called by muse, varscan2
- CD300C | c.78C>A p.S26R | Missense Mutation (SNP) | VAF 16/154 reads (10%) | SIFT tolerated (0.39); PolyPhen benign (0.06); catalogued as COSV100423238; called by muse, mutect2
- CDC42BPB | c.3077A>G p.H1026R | Missense Mutation (SNP) | VAF 16/53 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100775349; called by muse, mutect2, varscan2
- CDH19 | c.490G>A p.G164R | Missense Mutation (SNP) | VAF 17/52 reads (33%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as rs759949334, COSV100051332, COSV50959716; called by muse, mutect2, varscan2
- CDH3 | c.2362G>T p.D788Y | Missense Mutation (SNP) | VAF 79/234 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as COSV99867995; called by muse, mutect2, varscan2
- CDKN2A | c.143C>A p.P48Q | Missense Mutation (SNP) | VAF 152/274 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (0.934); catalogued as CM970251, COSV100446243, COSV58683273, COSV58688196; called by muse, mutect2, varscan2
- CEACAM8 | c.940A>G p.R314G | Missense Mutation (SNP) | VAF 72/163 reads (44%) | SIFT deleterious (0); PolyPhen benign (0.21); catalogued as COSV99747535; called by muse, mutect2, varscan2
- CLASP1 | c.2491G>T p.A831S | Missense Mutation (SNP) | VAF 56/147 reads (38%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.993); catalogued as rs1449286533, COSV99754124; called by muse, mutect2, varscan2
- CLEC1A | c.115+2T>C p.X39_splice | Splice Site (SNP) | VAF 13/27 reads (48%) | catalogued as rs1158301668, COSV100191329; called by muse, mutect2, varscan2
- CNNM2 | c.1045A>C p.T349P | Missense Mutation (SNP) | VAF 48/124 reads (39%) | SIFT deleterious (0.01); PolyPhen benign (0.16); catalogued as COSV100881697; called by muse, mutect2, varscan2
- COCH | c.947C>T p.T316I (on ENST00000216361 / NM_001347720.1; = p.T251I on NM_004086.3) | Missense Mutation (SNP) | VAF 19/42 reads (45%) | SIFT tolerated (0.37); PolyPhen probably damaging (0.962); catalogued as rs1416225513, COSV99363535; called by muse, mutect2, varscan2
- COL12A1 | c.5343G>T p.Q1781H | Missense Mutation (SNP) | VAF 16/36 reads (44%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.995); catalogued as COSV100485756; called by muse, mutect2
- COL4A2 | c.2912G>C p.G971A | Missense Mutation (SNP) | VAF 26/45 reads (58%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV100847304; called by muse, mutect2, varscan2
- COL6A1 | c.1441G>T p.E481* | Nonsense Mutation (SNP) | VAF 50/120 reads (42%) | catalogued as COSV100720103; called by muse, mutect2, varscan2
- COQ3 | c.283G>A p.G95S | Missense Mutation (SNP) | VAF 13/45 reads (29%) | SIFT tolerated (0.85); PolyPhen benign (0); catalogued as rs377313779, COSV99632526, COSV99632639; called by muse, mutect2, varscan2
- CPNE8 | c.1051G>T p.V351F | Missense Mutation (SNP) | VAF 27/74 reads (36%) | SIFT deleterious (0); PolyPhen benign (0.143); catalogued as COSV100504207; called by muse, mutect2, varscan2
- CRACD | c.2839G>A p.E947K | Missense Mutation (SNP) | VAF 9/43 reads (21%) | SIFT tolerated (0.52); PolyPhen benign (0.022); catalogued as COSV99949001; called by muse, mutect2, varscan2
- CRX | c.127C>A p.R43S | Missense Mutation (SNP) | VAF 32/134 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as CM163512, COSV55756817, COSV99704417; called by muse, mutect2, varscan2
- CSPG5 | c.872G>A p.G291D | Missense Mutation (SNP) | VAF 8/15 reads (53%) | SIFT tolerated, low confidence (0.11); PolyPhen possibly damaging (0.598); catalogued as rs751703859, COSV53130576; called by muse, mutect2, varscan2
- CTNNA2 | c.2295+2T>A p.X765_splice | Splice Site (SNP) | VAF 18/65 reads (28%) | catalogued as COSV100560024; called by muse, mutect2, varscan2
- CTU2 | c.817A>G p.I273V | Missense Mutation (SNP) | VAF 36/163 reads (22%) | SIFT tolerated (0.77); PolyPhen benign (0.38); catalogued as rs768661007, COSV99965728; called by muse, mutect2, varscan2
- CYP2R1 | c.517A>T p.K173* | Nonsense Mutation (SNP) | VAF 4/26 reads (15%) | catalogued as COSV100584898; called by muse, mutect2
- CYP4A22 | c.1189G>T p.V397F | Missense Mutation (SNP) | VAF 33/104 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.852); catalogued as COSV99594800; called by muse, mutect2, varscan2
- DAB1 | c.885del p.T296Lfs*70 (on ENST00000371231; = p.T263Lfs*70 on NM_021080.5 and 5 other RefSeq transcripts) | Frame Shift Del (DEL) | VAF 52/213 reads (24%) | catalogued as COSV104428367; called by mutect2, pindel, varscan2
- DCHS1 | c.5516T>A p.L1839Q | Missense Mutation (SNP) | VAF 14/24 reads (58%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.472); catalogued as COSV100201897; called by muse, mutect2, varscan2
- DDX53 | c.1727C>T p.S576L | Missense Mutation (SNP) | VAF 38/66 reads (58%) | SIFT tolerated (0.05); PolyPhen benign (0.023); catalogued as rs1353262448, COSV100029045, COSV60069952; called by muse, mutect2, varscan2
- DDX55 | c.1190A>G p.Q397R | Missense Mutation (SNP) | VAF 11/87 reads (13%) | SIFT tolerated (0.4); PolyPhen benign (0); catalogued as rs746695617, COSV99434368; called by muse, mutect2, varscan2
- DHRS9 | c.116C>T p.S39L | Missense Mutation (SNP) | VAF 34/80 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.932); catalogued as rs758163644, COSV100513420; called by muse, mutect2, varscan2
- DIO2 | c.376G>T p.V126F | Missense Mutation (SNP) | VAF 9/30 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV101375848, COSV70446622; called by muse, mutect2, varscan2
- DNAH17 | c.5714C>T p.S1905L | Missense Mutation (SNP) | VAF 10/44 reads (23%) | SIFT deleterious (0.03); PolyPhen benign (0.02); catalogued as COSV101101956, COSV101102660; called by muse, mutect2, varscan2
- DNAH9 | c.3995T>C p.M1332T | Missense Mutation (SNP) | VAF 10/28 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.948); catalogued as COSV52368917; called by muse, mutect2, varscan2
- DNAH9 | c.5634G>T p.E1878D | Missense Mutation (SNP) | VAF 30/122 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99305231; called by muse, varscan2
- DNAH9 | c.11880C>T p.N3960= | Splice Region (SNP) | VAF 5/22 reads (23%) | catalogued as COSV99305233; called by muse, mutect2
- DNASE1L3 | c.876A>T p.K292N | Missense Mutation (SNP) | VAF 16/33 reads (48%) | SIFT deleterious (0); PolyPhen benign (0.343); catalogued as rs774817141, COSV100568664; called by muse, mutect2, varscan2
- DOK6 | c.844T>C p.Y282H | Missense Mutation (SNP) | VAF 14/45 reads (31%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.615); catalogued as COSV101234420; called by muse, mutect2, varscan2
- DPP10 | c.2109+1G>T p.X703_splice | Splice Site (SNP) | VAF 18/49 reads (37%) | catalogued as COSV100062364; called by muse, mutect2, varscan2
- DUS3L | c.988G>T p.D330Y | Missense Mutation (SNP) | VAF 23/90 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100288082; called by muse, mutect2, varscan2
- DUSP4 | c.159C>A p.F53L | Missense Mutation (SNP) | VAF 11/16 reads (69%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99529761; called by muse, mutect2, varscan2
- EGLN3 | c.420C>G p.N140K | Missense Mutation (SNP) | VAF 56/177 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.817); catalogued as COSV99164319; called by muse, mutect2, varscan2
- EIF2S2 | c.973C>T p.R325* | Nonsense Mutation (SNP) | VAF 58/156 reads (37%) | catalogued as COSV66621482; called by muse, mutect2, varscan2
- EIF3F | c.460A>G p.K154E | Missense Mutation (SNP) | VAF 13/20 reads (65%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.474); catalogued as COSV59141258; called by muse, mutect2, varscan2
- EMC1 | c.1233G>T p.L411F | Missense Mutation (SNP) | VAF 98/179 reads (55%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.844); catalogued as COSV100916434; called by muse, mutect2, varscan2
- EML3 | c.1075G>A p.E359K | Missense Mutation (SNP) | VAF 96/348 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.852); catalogued as COSV99605851; called by muse, mutect2, varscan2
- EMX2 | c.151T>C p.F51L | Missense Mutation (SNP) | VAF 5/15 reads (33%) | SIFT tolerated (0.69); PolyPhen benign (0.005); catalogued as COSV101463590; called by muse, mutect2, varscan2
- EPN3 | c.431G>T p.R144L | Missense Mutation (SNP) | VAF 6/37 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV99276851; called by muse, mutect2, varscan2
- EPS8L1 | c.1342C>T p.R448W (on ENST00000201647 / NM_133180.3; = p.R321W on NM_017729.3) | Missense Mutation (SNP) | VAF 3/13 reads (23%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.639); catalogued as COSV99135846; called by muse, mutect2
- ERICH6 | c.1495G>T p.V499F | Missense Mutation (SNP) | VAF 8/48 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs773001250, COSV99901545; called by muse, varscan2
- ESRP2 | c.1018A>G p.I340V (on ENST00000565858 / NM_001365264.1; = p.I330V on NM_024939.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 28/83 reads (34%) | SIFT tolerated (0.56); PolyPhen benign (0.338); catalogued as COSV99251224; called by muse, mutect2, varscan2
- ESRRG | c.434G>A p.C145Y | Missense Mutation (SNP) | VAF 33/90 reads (37%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.996); catalogued as COSV100752655; called by muse, mutect2, varscan2
- FAT3 | c.2445A>T p.R815S | Missense Mutation (SNP) | VAF 17/54 reads (31%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.894); catalogued as COSV99964569; called by muse, mutect2, varscan2
- FAT3 | c.5044G>A p.E1682K | Missense Mutation (SNP) | VAF 30/87 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99964572; called by muse, mutect2, varscan2
- FBXO46 | c.587C>T p.P196L | Missense Mutation (SNP) | VAF 18/30 reads (60%) | SIFT deleterious (0); PolyPhen possibly damaging (0.608); catalogued as COSV100480123; called by muse, mutect2, varscan2
- FBXW12 | c.564G>T p.Q188H | Missense Mutation (SNP) | VAF 12/31 reads (39%) | SIFT tolerated (0.55); PolyPhen benign (0); catalogued as COSV56485783, COSV99601560; called by muse, mutect2, varscan2
- FCRL5 | c.1274C>G p.S425W | Missense Mutation (SNP) | VAF 21/73 reads (29%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.993); catalogued as COSV100708778, COSV62519819; called by muse, mutect2, varscan2
- FCRL6 | c.1219C>A p.P407T | Missense Mutation (SNP) | VAF 29/107 reads (27%) | SIFT tolerated (0.19); PolyPhen benign (0.013); catalogued as COSV100220147; called by muse, mutect2, varscan2
- FLT4 | c.2128G>A p.V710M | Missense Mutation (SNP) | VAF 14/83 reads (17%) | SIFT tolerated (0.27); PolyPhen benign (0.017); catalogued as rs758234191, COSV56097902, COSV56099457; called by muse, mutect2, varscan2
- FMN2 | c.1523C>T p.A508V | Missense Mutation (SNP) | VAF 4/11 reads (36%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.025); catalogued as rs376836605, COSV100144460; called by muse, varscan2
- FN1 | c.4668C>A p.N1556K | Missense Mutation (SNP) | VAF 41/115 reads (36%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.526); catalogued as COSV100116826; called by muse, mutect2, varscan2
- FN1 | c.496G>C p.E166Q | Missense Mutation (SNP) | VAF 60/172 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100116782; called by muse, mutect2, varscan2
- FOXR1 | c.409G>A p.D137N | Missense Mutation (SNP) | VAF 43/112 reads (38%) | SIFT tolerated (0.12); PolyPhen benign (0.003); catalogued as COSV100392872, COSV57653349; called by muse, mutect2, varscan2
- FOXRED2 | c.829G>T p.G277W | Missense Mutation (SNP) | VAF 22/77 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1333459998, COSV99340815, COSV99341205; called by muse, mutect2, varscan2
- FREM1 | c.5734C>T p.R1912W | Missense Mutation (SNP) | VAF 31/54 reads (57%) | SIFT tolerated (0.07); PolyPhen benign (0); catalogued as rs747877946, COSV66529835; called by muse, mutect2, varscan2
- FTHL17 | c.436A>C p.I146L | Missense Mutation (SNP) | VAF 49/69 reads (71%) | SIFT tolerated (0.1); PolyPhen benign (0.018); catalogued as COSV100784277; called by muse, mutect2, varscan2
- FYCO1 | c.1660G>T p.E554* | Nonsense Mutation (SNP) | VAF 25/49 reads (51%) | catalogued as COSV99945478; called by muse, mutect2, varscan2
- GABRG1 | c.685G>T p.D229Y | Missense Mutation (SNP) | VAF 8/24 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV54953934, COSV99777743; called by muse, mutect2, varscan2
- GAS2L1 | c.740G>T p.R247L | Missense Mutation (SNP) | VAF 38/105 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV99329470; called by muse, mutect2, varscan2
- GCG | c.26G>T p.G9V | Missense Mutation (SNP) | VAF 50/146 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.927); catalogued as COSV100972748; called by muse, mutect2, varscan2
- GDPD5 | c.206A>G p.Y69C | Missense Mutation (SNP) | VAF 23/62 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.922); catalogued as rs992173764, COSV100409235; called by muse, mutect2, varscan2
- GRIK2 | c.1672C>T p.P558S | Missense Mutation (SNP) | VAF 55/165 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59738103; called by muse, mutect2, varscan2
- GRIN2B | c.2476G>T p.G826W | Missense Mutation (SNP) | VAF 35/135 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.971); catalogued as COSV101662999; called by muse, mutect2, varscan2
- GSTM2 | c.394C>T p.P132S | Missense Mutation (SNP) | VAF 28/104 reads (27%) | SIFT deleterious (0.02); PolyPhen benign (0.301); catalogued as rs267597909, COSV99598127; called by muse, varscan2
- H2AX | c.85G>T p.G29C | Missense Mutation (SNP) | VAF 6/14 reads (43%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.998); catalogued as COSV99597900; called by muse, mutect2, varscan2
- HDAC2 | c.325G>C p.E109Q | Missense Mutation (SNP) | VAF 12/36 reads (33%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV64037331; called by muse, mutect2, varscan2
- HERC2 | c.857A>T p.Q286L | Missense Mutation (SNP) | VAF 33/119 reads (28%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.838); catalogued as COSV99872565; called by muse, mutect2, varscan2
- HIPK1 | c.1823C>G p.S608* | Nonsense Mutation (SNP) | VAF 14/123 reads (11%) | catalogued as COSV100478803; called by muse, mutect2, varscan2
- HLA-F | c.203C>G p.P68R | Missense Mutation (SNP) | VAF 9/17 reads (53%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.878); catalogued as COSV99465890; called by muse, mutect2, varscan2
- HMGXB4 | c.576G>C p.M192I | Missense Mutation (SNP) | VAF 56/174 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.977); catalogued as COSV99330007; called by muse, mutect2, varscan2
- HOXB2 | c.971C>A p.P324H | Missense Mutation (SNP) | VAF 25/105 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.65); catalogued as COSV100344549; called by muse, mutect2, varscan2
- HPS3 | c.1779G>T p.W593C | Missense Mutation (SNP) | VAF 44/156 reads (28%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.489); catalogued as COSV99937331; called by muse, mutect2, varscan2
- HSDL1 | c.454G>A p.V152M | Missense Mutation (SNP) | VAF 53/155 reads (34%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.975); catalogued as rs533488568, COSV99550332; called by muse, mutect2, varscan2
- HTR4 | c.264T>A p.Y88* | Nonsense Mutation (SNP) | VAF 27/40 reads (68%) | catalogued as COSV100087684; called by muse, mutect2, varscan2
- HUNK | c.1067G>T p.G356V | Missense Mutation (SNP) | VAF 56/165 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as COSV99528336; called by muse, mutect2, varscan2
- IGHV3-48 | c.257G>T p.R86L | Missense Mutation (SNP) | VAF 63/214 reads (29%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.451); catalogued as rs375311726; called by muse, mutect2, varscan2
- INTS7 | c.484G>T p.A162S | Missense Mutation (SNP) | VAF 16/50 reads (32%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.934); catalogued as COSV100877462; called by muse, mutect2, varscan2
- IQCN | c.1220C>T p.P407L | Missense Mutation (SNP) | VAF 20/110 reads (18%) | SIFT tolerated (0.06); PolyPhen benign (0.001); catalogued as COSV66578000; called by muse, mutect2, varscan2
- IQGAP3 | c.3817G>A p.A1273T | Missense Mutation (SNP) | VAF 54/182 reads (30%) | SIFT tolerated (1); PolyPhen benign (0.141); catalogued as COSV100752116; called by muse, mutect2, varscan2
- ITGAV | c.1231A>G p.T411A | Missense Mutation (SNP) | VAF 35/89 reads (39%) | SIFT tolerated (0.6); PolyPhen benign (0.001); catalogued as rs749248681, COSV99654673; called by muse, mutect2, varscan2
- ITGAX | c.213C>A p.Y71* | Nonsense Mutation (SNP) | VAF 6/21 reads (29%) | catalogued as COSV99191593; called by muse, mutect2, varscan2
- IZUMO2 | c.548C>A p.P183Q | Missense Mutation (SNP) | VAF 40/204 reads (20%) | SIFT tolerated (0.42); PolyPhen benign (0.003); catalogued as rs199749467, COSV99518159, COSV99518220; called by muse, mutect2, varscan2
- JADE2 | c.1889G>C p.G630A | Missense Mutation (SNP) | VAF 68/98 reads (69%) | SIFT tolerated (0.88); PolyPhen benign (0); catalogued as COSV99253032; called by muse, mutect2, varscan2
- JSRP1 | c.820C>T p.R274W | Missense Mutation (SNP) | VAF 29/67 reads (43%) | SIFT deleterious (0); PolyPhen benign (0.005); catalogued as COSV99677717; called by muse, mutect2, varscan2
- JUNB | c.687G>T p.Q229H | Missense Mutation (SNP) | VAF 6/17 reads (35%) | SIFT tolerated (0.45); PolyPhen benign (0.291); catalogued as COSV100040158; called by muse, mutect2, varscan2
- KATNIP | c.2848T>C p.S950P | Missense Mutation (SNP) | VAF 21/63 reads (33%) | SIFT tolerated (0.82); PolyPhen benign (0.134); catalogued as COSV99850709; called by muse, mutect2, varscan2
- KMT2C | c.2909C>A p.A970E | Missense Mutation (SNP) | VAF 23/256 reads (9%) | SIFT deleterious (0.04); PolyPhen benign (0.046); catalogued as COSV51523884; called by muse, mutect2
- KMT2D | c.13630G>T p.G4544W | Missense Mutation (SNP) | VAF 14/28 reads (50%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.962); catalogued as COSV99979941; called by muse, mutect2, varscan2
- KRI1 | c.1888C>G p.P630A | Missense Mutation (SNP) | VAF 37/95 reads (39%) | SIFT tolerated (0.43); PolyPhen benign (0.024); catalogued as COSV100469960; called by muse, mutect2, varscan2
- KRTAP9-9 | c.302G>T p.G101V | Missense Mutation (SNP) | VAF 70/154 reads (45%) | SIFT tolerated (0.06); catalogued as COSV101223510; called by muse, mutect2, varscan2
- L3MBTL4 | c.1287G>C p.L429F | Missense Mutation (SNP) | VAF 26/34 reads (76%) | SIFT tolerated (0.11); PolyPhen benign (0.005); catalogued as COSV99528420, COSV99529280; called by muse, mutect2, varscan2
- LAMA1 | c.2195G>A p.G732E | Missense Mutation (SNP) | VAF 20/32 reads (63%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV101055882; called by muse, mutect2, varscan2
- LAMC1 | c.3952G>A p.E1318K | Missense Mutation (SNP) | VAF 26/70 reads (37%) | SIFT tolerated (0.32); PolyPhen benign (0.091); catalogued as COSV51172126; called by muse, mutect2, varscan2
- LCA5 | c.1300C>G p.P434A | Missense Mutation (SNP) | VAF 12/29 reads (41%) | SIFT tolerated (0.24); PolyPhen benign (0.225); catalogued as COSV100878229; called by muse, mutect2, varscan2
- LGR6 | c.973A>T p.K325* (on ENST00000367278 / NM_001017403.1; = p.K273* on NM_021636.3) | Nonsense Mutation (SNP) | VAF 32/107 reads (30%) | catalogued as COSV99706556; called by muse, mutect2, varscan2
- LGSN | c.242C>A p.A81D | Missense Mutation (SNP) | VAF 22/65 reads (34%) | SIFT tolerated (0.11); PolyPhen benign (0.02); catalogued as COSV101040439; called by muse, mutect2, varscan2
- LILRA5 | c.180del p.N61Tfs*3 | Frame Shift Del (DEL) | VAF 19/86 reads (22%) | catalogued as COSV56642847; called by mutect2, pindel, varscan2
- LIPI | c.572A>T p.K191M | Missense Mutation (SNP) | VAF 27/84 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100753597, COSV60714409; called by muse, mutect2, varscan2
- LRP12 | c.1069G>A p.D357N | Missense Mutation (SNP) | VAF 60/114 reads (53%) | SIFT tolerated (0.27); PolyPhen benign (0.028); catalogued as COSV99407513; called by muse, mutect2, varscan2
- LRP4 | c.1222G>T p.G408C | Missense Mutation (SNP) | VAF 48/175 reads (27%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.829); catalogued as COSV101066506; called by muse, mutect2, varscan2
- LRR1 | c.1202G>C p.C401S | Missense Mutation (SNP) | VAF 7/28 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV100023062; called by muse, mutect2, varscan2
- LRRIQ4 | c.253A>G p.S85G | Missense Mutation (SNP) | VAF 23/147 reads (16%) | SIFT tolerated (0.35); PolyPhen benign (0.003); catalogued as COSV100540178; called by muse, mutect2, varscan2
- LZTR1 | c.154C>A p.H52N | Missense Mutation (SNP) | VAF 12/61 reads (20%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.838); catalogued as COSV99301590; called by muse, mutect2, varscan2
- LZTR1 | c.155A>T p.H52L | Missense Mutation (SNP) | VAF 13/61 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.888); catalogued as COSV99301594; called by muse, mutect2, varscan2
- MAB21L3 | c.879G>T p.E293D | Missense Mutation (SNP) | VAF 21/72 reads (29%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.829); catalogued as COSV101046347; called by muse, mutect2, varscan2
- MAD2L2 | c.536T>C p.V179A | Missense Mutation (SNP) | VAF 30/50 reads (60%) | SIFT tolerated (0.09); PolyPhen benign (0.211); catalogued as rs777238058, COSV99335900; called by muse, mutect2, varscan2
- MAFA | c.814C>G p.R272G | Missense Mutation (SNP) | VAF 11/16 reads (69%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV100339146; called by muse, mutect2, varscan2
- MAGEA8 | c.244C>T p.Q82* | Nonsense Mutation (SNP) | VAF 95/113 reads (84%) | catalogued as COSV99674517; called by muse, mutect2, varscan2
- MAP1A | c.2531C>T p.S844L | Missense Mutation (SNP) | VAF 18/51 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100288434, COSV55811857; called by muse, mutect2, varscan2
- MARCHF7 | c.1172G>C p.R391T | Missense Mutation (SNP) | VAF 36/79 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as rs1366251150, COSV99373681; called by muse, mutect2, varscan2
- MB | c.362C>G p.P121R | Missense Mutation (SNP) | VAF 52/113 reads (46%) | SIFT tolerated (0.06); PolyPhen benign (0.35); catalogued as COSV100704716; called by muse, mutect2, varscan2
- MEP1A | c.1695G>C p.L565F | Missense Mutation (SNP) | VAF 40/119 reads (34%) | SIFT tolerated (0.43); PolyPhen benign (0.001); catalogued as COSV100042567; called by muse, mutect2
- METTL16 | c.1298G>T p.G433V | Missense Mutation (SNP) | VAF 58/133 reads (44%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0); catalogued as COSV99563292; called by muse, mutect2, varscan2
- MLXIPL | c.1709C>G p.P570R | Missense Mutation (SNP) | VAF 5/11 reads (45%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.878); catalogued as COSV100515277, COSV57668320; called by muse, mutect2, varscan2
- MMAA | c.1036C>G p.Q346E | Missense Mutation (SNP) | VAF 31/71 reads (44%) | SIFT tolerated (0.07); PolyPhen benign (0.079); catalogued as COSV55579625, COSV99849754; called by muse, mutect2, varscan2
- MMP8 | c.457C>A p.Q153K | Missense Mutation (SNP) | VAF 15/49 reads (31%) | SIFT tolerated (0.41); PolyPhen benign (0.001); catalogued as COSV52634258; called by muse, mutect2, varscan2
- MTNR1B | c.1031G>T p.G344V | Missense Mutation (SNP) | VAF 46/114 reads (40%) | SIFT tolerated (0.17); PolyPhen benign (0.001); catalogued as COSV99925054; called by muse, mutect2, varscan2
- MTR | c.2032G>T p.A678S | Missense Mutation (SNP) | VAF 18/72 reads (25%) | SIFT tolerated (0.16); PolyPhen benign (0.383); catalogued as rs759130222, COSV100855332, COSV63964509; called by muse, mutect2, varscan2
- MUC16 | c.43242G>A p.M14414I | Missense Mutation (SNP) | VAF 12/19 reads (63%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.047); catalogued as COSV101109806; called by muse, mutect2, varscan2
- MYH4 | c.1298C>G p.A433G | Missense Mutation (SNP) | VAF 110/347 reads (32%) | SIFT deleterious (0.04); PolyPhen benign (0.025); catalogued as COSV99700959; called by muse, mutect2, varscan2
- MYH4 | c.169G>C p.G57R | Missense Mutation (SNP) | VAF 57/211 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.652); catalogued as rs780288488, COSV99700961, COSV99701309; called by muse, mutect2, varscan2
- MYH8 | c.1042G>C p.E348Q | Missense Mutation (SNP) | VAF 39/95 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101238359; called by muse, mutect2, varscan2
- N4BP2 | c.2512G>T p.V838F | Missense Mutation (SNP) | VAF 10/73 reads (14%) | SIFT tolerated (0.16); PolyPhen benign (0.034); catalogued as COSV99788506; called by muse, mutect2, varscan2
- NACC2 | c.1158-1G>T p.X386_splice | Splice Site (SNP) | VAF 67/139 reads (48%) | catalogued as COSV99508289; called by muse, mutect2, varscan2
- NCAPD3 | c.1169A>G p.Y390C | Missense Mutation (SNP) | VAF 21/71 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); catalogued as COSV101596363; called by muse, mutect2, varscan2
- NEDD9 | c.202C>G p.Q68E | Missense Mutation (SNP) | VAF 38/97 reads (39%) | SIFT tolerated (0.28); PolyPhen benign (0.012); catalogued as COSV101053387; called by muse, mutect2, varscan2
- NFASC | c.1708A>T p.M570L (on ENST00000339876 / NM_001378329.1; = p.M581L on NM_015090.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 190/508 reads (37%) | SIFT tolerated (0.42); PolyPhen benign (0); catalogued as COSV100363441; called by muse, mutect2, varscan2
- NLRP11 | c.341G>A p.G114E | Missense Mutation (SNP) | VAF 4/42 reads (10%) | SIFT tolerated (1); PolyPhen benign (0.379); catalogued as rs1265659363, COSV64085660; called by muse, mutect2
- NLRP8 | c.1540T>A p.F514I | Missense Mutation (SNP) | VAF 77/181 reads (43%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.838); catalogued as COSV99405093; called by muse, mutect2, varscan2
- NOTCH1 | c.294C>A p.C98* | Nonsense Mutation (SNP) | VAF 45/52 reads (87%) | catalogued as COSV99486875; called by muse, mutect2, varscan2
- NOTCH3 | c.5240G>T p.C1747F | Missense Mutation (SNP) | VAF 35/87 reads (40%) | SIFT tolerated (0.66); PolyPhen possibly damaging (0.629); catalogued as COSV54643443, COSV99656738; called by muse, mutect2, varscan2
- NPEPPS | c.1153T>C p.C385R | Missense Mutation (SNP) | VAF 6/36 reads (17%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.969); catalogued as COSV100443561; called by muse, mutect2
- NPFFR2 | c.1405G>A p.A469T | Missense Mutation (SNP) | VAF 3/28 reads (11%) | SIFT tolerated (0.14); PolyPhen benign (0.003); catalogued as COSV100440555, COSV58151115; called by muse, mutect2
- NR2E1 | c.100G>A p.D34N | Missense Mutation (SNP) | VAF 63/267 reads (24%) | SIFT tolerated (0.25); PolyPhen probably damaging (1); catalogued as COSV100934455; called by muse, mutect2, varscan2
- NR3C2 | c.1378T>A p.F460I | Missense Mutation (SNP) | VAF 9/38 reads (24%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.391); catalogued as COSV100678894; called by muse, mutect2, varscan2
- NRXN3 | c.261C>A p.Y87* (on ENST00000557594 / NM_001272020.2; = p.Y719* on NM_004796.6) | Nonsense Mutation (SNP) | VAF 22/88 reads (25%) | catalogued as COSV99817783; called by muse, mutect2, varscan2
- OPHN1 | c.2249G>A p.R750Q | Missense Mutation (SNP) | VAF 18/41 reads (44%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.375); catalogued as rs765116282, COSV100830360; called by muse, mutect2, varscan2
- OR2M5 | c.349G>A p.V117I | Missense Mutation (SNP) | VAF 101/338 reads (30%) | SIFT tolerated (0.15); PolyPhen benign (0.009); catalogued as rs757378386, COSV100822792, COSV100822860, COSV63545947; called by muse, mutect2, varscan2
- OR4C13 | c.209G>T p.C70F | Missense Mutation (SNP) | VAF 58/252 reads (23%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.013); catalogued as COSV101634160; called by muse, mutect2, varscan2
- OR4K14 | c.928C>G p.Q310E | Missense Mutation (SNP) | VAF 44/130 reads (34%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.007); catalogued as COSV100520383, COSV59292571; called by muse, mutect2, varscan2
- OR5H1 | c.823C>A p.P275T | Missense Mutation (SNP) | VAF 23/69 reads (33%) | SIFT deleterious (0.01); PolyPhen benign (0.045); catalogued as COSV100641671; called by muse, mutect2, varscan2
- OR5L1 | c.668C>A p.T223N | Missense Mutation (SNP) | VAF 60/149 reads (40%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.612); catalogued as COSV61735486; called by muse, mutect2, varscan2
- OR6B2 | c.774G>T p.M258I | Missense Mutation (SNP) | VAF 20/53 reads (38%) | SIFT tolerated (0.64); PolyPhen benign (0.027); catalogued as COSV99401368; called by muse, mutect2, varscan2
- OR6C74 | c.880C>A p.Q294K | Missense Mutation (SNP) | VAF 16/33 reads (48%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.487); catalogued as COSV100667717; called by muse, mutect2
- OR8I2 | c.823G>T p.V275L | Missense Mutation (SNP) | VAF 23/64 reads (36%) | SIFT deleterious (0.02); PolyPhen benign (0.033); catalogued as COSV100136000; called by muse, mutect2, varscan2
- OR8K3 | c.671C>A p.A224D | Missense Mutation (SNP) | VAF 13/50 reads (26%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.905); catalogued as COSV100449734; called by muse, mutect2, varscan2
- OR9G4 | c.20C>A p.T7N | Missense Mutation (SNP) | VAF 33/116 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV100265088; called by muse, mutect2, varscan2
- PAX6 | c.1234C>A p.P412T | Missense Mutation (SNP) | VAF 21/51 reads (41%) | SIFT tolerated (0.13); PolyPhen benign (0.003); catalogued as COSV99570314; called by muse, mutect2, varscan2
- PCDHGA2 | c.8C>T p.A3V | Missense Mutation (SNP) | VAF 29/37 reads (78%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.006); catalogued as COSV66952648; called by muse, mutect2, varscan2
- PER2 | c.921G>T p.Q307H | Missense Mutation (SNP) | VAF 12/87 reads (14%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.896); catalogued as COSV99611716; called by muse, mutect2, varscan2
- PER2 | c.920A>T p.Q307L | Missense Mutation (SNP) | VAF 12/87 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.754); catalogued as COSV99611719; called by muse, mutect2, varscan2
- PFKFB2 | c.987T>G p.A329= | Splice Region (SNP) | VAF 9/33 reads (27%) | catalogued as COSV65547956; called by muse, mutect2, varscan2
- PHLDA1 | c.466C>G p.L156V | Missense Mutation (SNP) | VAF 8/40 reads (20%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.058); catalogued as COSV99876589; called by muse, mutect2, varscan2
- PHLPP2 | c.3571A>T p.T1191S | Missense Mutation (SNP) | VAF 31/103 reads (30%) | SIFT tolerated (0.73); PolyPhen benign (0.006); catalogued as COSV100673612; called by muse, mutect2, varscan2
- PI4K2B | c.895A>G p.I299V | Missense Mutation (SNP) | VAF 10/36 reads (28%) | SIFT tolerated (0.14); PolyPhen benign (0.173); catalogued as rs765925650, COSV99335429; called by muse, mutect2, varscan2
- PKHD1 | c.4345G>C p.G1449R | Missense Mutation (SNP) | VAF 34/87 reads (39%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.869); catalogued as COSV100582457; called by muse, mutect2, varscan2
- PLCG2 | c.2303C>T p.S768F | Missense Mutation (SNP) | VAF 21/84 reads (25%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.581); catalogued as COSV100842172; called by muse, mutect2, varscan2
- PLD5 | c.928G>C p.V310L (on ENST00000442594; = p.V248L on NM_001195811.1 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 9/35 reads (26%) | SIFT tolerated (0.79); PolyPhen probably damaging (0.93); catalogued as COSV100139805; called by muse, mutect2, varscan2
- PLEKHN1 | c.327C>A p.S109R | Missense Mutation (SNP) | VAF 54/99 reads (55%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.974); catalogued as COSV100379041; called by muse, mutect2, varscan2
- PNMA2 | c.343C>A p.Q115K | Missense Mutation (SNP) | VAF 37/64 reads (58%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.899); catalogued as COSV101580612; called by muse, mutect2, varscan2
- PNMA3 | c.455T>C p.V152A | Missense Mutation (SNP) | VAF 59/73 reads (81%) | SIFT tolerated (0.37); PolyPhen benign (0.007); catalogued as rs926461175, COSV64721914; called by muse, mutect2, varscan2
- POLRMT | c.3350A>T p.N1117I | Missense Mutation (SNP) | VAF 22/61 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99241595; called by muse, mutect2, varscan2
- PPARGC1A | c.696C>A p.S232R | Missense Mutation (SNP) | VAF 39/113 reads (35%) | SIFT tolerated (0.14); PolyPhen benign (0.001); catalogued as COSV53526337; called by muse, mutect2, varscan2
- PPFIA2 | c.545A>T p.E182V | Missense Mutation (SNP) | VAF 22/50 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV100332746; called by muse, mutect2, varscan2
- PPIG | c.546A>C p.K182N | Missense Mutation (SNP) | VAF 46/102 reads (45%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as COSV99644401; called by muse, mutect2, varscan2
- PPP1R13L | c.760G>T p.D254Y | Missense Mutation (SNP) | VAF 41/100 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.65); catalogued as COSV100714718, COSV62908640; called by muse, mutect2, varscan2
- PROX1 | c.2028G>T p.E676D | Missense Mutation (SNP) | VAF 23/73 reads (32%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.927); catalogued as COSV99799081; called by muse, mutect2, varscan2
- PTGIR | c.438C>G p.F146L | Missense Mutation (SNP) | VAF 5/27 reads (19%) | SIFT tolerated (0.18); PolyPhen benign (0.147); catalogued as COSV52191722, COSV52193802; called by muse, mutect2, varscan2
- PTPRO | c.1444G>C p.E482Q | Missense Mutation (SNP) | VAF 10/35 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV55504336, COSV55504926; called by muse, mutect2, varscan2
- PZP | c.3908T>C p.L1303P | Missense Mutation (SNP) | VAF 38/109 reads (35%) | SIFT deleterious (0); PolyPhen benign (0.136); catalogued as COSV99737302; called by muse, mutect2, varscan2
- QTRT1 | c.848C>T p.P283L | Missense Mutation (SNP) | VAF 117/286 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51552745; called by muse, varscan2
- RAI1 | c.4667G>T p.R1556L | Missense Mutation (SNP) | VAF 45/137 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.621); catalogued as COSV99883799; called by muse, mutect2, varscan2
- RALGDS | c.1048G>A p.E350K | Missense Mutation (SNP) | VAF 60/119 reads (50%) | SIFT tolerated (0.08); PolyPhen benign (0.015); catalogued as COSV100924369; called by muse, mutect2, varscan2
- RARG | c.64G>T p.G22W | Missense Mutation (SNP) | VAF 16/34 reads (47%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.407); catalogued as COSV59534850; called by muse, mutect2, varscan2
- RAVER2 | c.377A>G p.Y126C | Missense Mutation (SNP) | VAF 26/54 reads (48%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.87); catalogued as COSV99605032; called by muse, mutect2, varscan2
- RBM25 | c.1698A>T p.E566D | Missense Mutation (SNP) | VAF 7/21 reads (33%) | SIFT tolerated (0.12); PolyPhen benign (0.122); catalogued as COSV99998592; called by muse, mutect2, varscan2
- RBM47 | c.1542+2T>C p.X514_splice (on ENST00000295971 / NM_001098634.2; = p.X445_splice on NM_019027.4) | Splice Site (SNP) | VAF 50/109 reads (46%) | catalogued as COSV99920543; called by muse, mutect2, varscan2
- RECQL4 | c.2707G>A p.A903T | Missense Mutation (SNP) | VAF 5/10 reads (50%) | SIFT deleterious (0.03); PolyPhen benign (0.248); catalogued as COSV100020428; called by muse, mutect2, varscan2
- REG1A | c.82G>T p.E28* | Nonsense Mutation (SNP) | VAF 86/258 reads (33%) | catalogued as COSV52070589, COSV99286746; called by muse, mutect2, varscan2
- REG1A | c.400C>A p.P134T | Missense Mutation (SNP) | VAF 30/113 reads (27%) | SIFT tolerated (0.16); PolyPhen benign (0.001); catalogued as rs1263232216, COSV99286747; called by muse, mutect2, varscan2
- RINL | c.445C>A p.H149N (on ENST00000591812 / NM_001195833.2; = p.H35N on NM_198445.4) | Missense Mutation (SNP) | VAF 18/102 reads (18%) | SIFT tolerated (0.2); PolyPhen benign (0); catalogued as COSV100531100; called by muse, mutect2, varscan2
- RNASE11 | c.572G>T p.S191I | Missense Mutation (SNP) | VAF 23/73 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV100250488; called by muse, mutect2, varscan2
- RNF126 | c.667G>A p.V223I | Missense Mutation (SNP) | VAF 5/20 reads (25%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.76); catalogued as rs756568943, COSV99443032; called by muse, mutect2, varscan2
- RNF208 | c.203C>G p.S68* | Nonsense Mutation (SNP) | VAF 4/26 reads (15%) | catalogued as COSV61286445; called by muse, varscan2
- RUFY3 | c.20C>T p.P7L | Missense Mutation (SNP) | VAF 25/112 reads (22%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.019); catalogued as rs143545853; called by muse, mutect2, varscan2
- RYR1 | c.9005T>A p.L3002Q | Missense Mutation (SNP) | VAF 120/330 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.921); catalogued as COSV100615381; called by muse, mutect2, varscan2
- RYR2 | c.12916T>A p.F4306I | Missense Mutation (SNP) | VAF 15/51 reads (29%) | SIFT tolerated (0.07); PolyPhen benign (0.046); catalogued as COSV100769401; called by muse, mutect2, varscan2
- S100A7 | c.115A>T p.N39Y | Missense Mutation (SNP) | VAF 83/211 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as COSV100906720; called by muse, mutect2, varscan2
- SAMD14 | c.133C>T p.R45W | Missense Mutation (SNP) | VAF 36/113 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1238588578, COSV99557406; called by muse, mutect2, varscan2
- SCFD2 | c.457G>C p.V153L | Missense Mutation (SNP) | VAF 30/98 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.978); catalogued as COSV101189334; called by muse, mutect2, varscan2
- SECISBP2L | c.201T>A p.N67K | Missense Mutation (SNP) | VAF 10/28 reads (36%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.906); catalogued as COSV99960151; called by muse, mutect2, varscan2
- SELE | c.829G>C p.E277Q | Missense Mutation (SNP) | VAF 31/103 reads (30%) | SIFT tolerated (0.48); PolyPhen possibly damaging (0.606); catalogued as COSV60976937; called by muse, mutect2, varscan2
- SLC17A8 | c.841A>T p.N281Y | Missense Mutation (SNP) | VAF 6/31 reads (19%) | SIFT deleterious (0.02); PolyPhen benign (0.113); catalogued as COSV100035403; called by muse, mutect2, varscan2
- SLC1A6 | c.394G>T p.A132S | Missense Mutation (SNP) | VAF 17/50 reads (34%) | SIFT tolerated (0.07); PolyPhen benign (0.014); catalogued as COSV99693585; called by muse, mutect2, varscan2
- SLC1A6 | c.110C>G p.T37R | Missense Mutation (SNP) | VAF 3/9 reads (33%) | SIFT tolerated (0.06); PolyPhen benign (0.422); catalogued as COSV55673390, COSV99693589; called by muse, mutect2
- SLC22A2 | c.739G>T p.V247F | Missense Mutation (SNP) | VAF 50/158 reads (32%) | SIFT tolerated (0.14); PolyPhen benign (0.098); catalogued as COSV100870969; called by muse, mutect2, varscan2
- SLC25A16 | c.571G>T p.G191C | Missense Mutation (SNP) | VAF 21/48 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99770069; called by muse, mutect2, varscan2
- SLC26A11 | c.872C>T p.T291I | Missense Mutation (SNP) | VAF 17/148 reads (11%) | SIFT tolerated (0.1); PolyPhen benign (0.053); catalogued as COSV100755352; called by muse, mutect2, varscan2
- SLC28A1 | c.277+1G>T p.X93_splice | Splice Site (SNP) | VAF 9/22 reads (41%) | catalogued as COSV99722859; called by muse, mutect2, varscan2
- SLC30A6 | c.666-2A>T p.X222_splice | Splice Site (SNP) | VAF 16/48 reads (33%) | catalogued as COSV99249545; called by muse, mutect2, varscan2
- SLC8A3 | c.209T>C p.L70P | Missense Mutation (SNP) | VAF 20/58 reads (34%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.746); catalogued as rs200366563, COSV100776080; called by muse, mutect2, varscan2
- SLCO1B3-SLCO1B7 | c.2150C>A p.T717N (on ENST00000540229 / NM_001371097.1; = p.T656N on NM_001009562.4) | Missense Mutation (SNP) | VAF 6/16 reads (38%) | SIFT tolerated (0.34); PolyPhen benign (0.206); catalogued as COSV101043496; called by muse, varscan2
- SLITRK4 | c.1147C>A p.H383N | Missense Mutation (SNP) | VAF 106/131 reads (81%) | SIFT deleterious (0.01); PolyPhen benign (0.05); catalogued as COSV100567269; called by muse, mutect2, varscan2
- SNX16 | c.977A>G p.E326G | Missense Mutation (SNP) | VAF 52/110 reads (47%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0); catalogued as COSV100629572; called by muse, mutect2, varscan2
- SPART | c.1771G>T p.V591L | Missense Mutation (SNP) | VAF 19/33 reads (58%) | SIFT tolerated (0.34); PolyPhen possibly damaging (0.705); catalogued as COSV100768661; called by muse, mutect2, varscan2
- SPATA5L1 | c.584A>T p.Q195L | Missense Mutation (SNP) | VAF 6/13 reads (46%) | SIFT tolerated (0.1); PolyPhen benign (0); catalogued as COSV99972977; called by muse, mutect2, varscan2
- SPG11 | c.3535C>T p.L1179F | Missense Mutation (SNP) | VAF 41/98 reads (42%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.995); catalogued as rs1238379023, COSV99968401; called by muse, mutect2, varscan2
- SPICE1 | c.602A>G p.N201S | Missense Mutation (SNP) | VAF 24/73 reads (33%) | SIFT tolerated (0.26); PolyPhen benign (0.015); catalogued as rs753158033, COSV55625722; called by muse, mutect2, varscan2
- SPNS1 | c.450C>G p.F150L | Missense Mutation (SNP) | VAF 49/157 reads (31%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.612); catalogued as COSV100209023; called by muse, mutect2, varscan2
- SPTA1 | c.1024C>A p.Q342K | Missense Mutation (SNP) | VAF 81/250 reads (32%) | SIFT tolerated (0.27); PolyPhen benign (0.013); catalogued as COSV100934702; called by muse, mutect2, varscan2
- SPTBN5 | c.10490C>A p.P3497H | Missense Mutation (SNP) | VAF 5/19 reads (26%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.919); catalogued as COSV100311137; called by muse, mutect2, varscan2
- SRGAP1 | c.1939G>T p.E647* | Nonsense Mutation (SNP) | VAF 23/44 reads (52%) | catalogued as COSV100754503; called by muse, mutect2, varscan2
- SRRM4 | c.1216C>T p.R406* | Nonsense Mutation (SNP) | VAF 29/135 reads (21%) | catalogued as rs373815603, COSV57414549; called by muse, mutect2, varscan2
- ST6GAL2 | c.926C>A p.S309Y | Missense Mutation (SNP) | VAF 4/25 reads (16%) | PolyPhen benign (0.316); catalogued as COSV64527446, COSV64532993; called by muse, mutect2, varscan2
- STK31 | c.2589A>T p.L863F | Missense Mutation (SNP) | VAF 28/84 reads (33%) | SIFT deleterious (0.01); PolyPhen benign (0.17); catalogued as COSV100669285; called by muse, mutect2, varscan2
- SUOX | c.1458G>C p.W486C | Missense Mutation (SNP) | VAF 39/126 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99907008; called by muse, mutect2, varscan2
- SVEP1 | c.3151G>A p.D1051N | Missense Mutation (SNP) | VAF 15/69 reads (22%) | SIFT deleterious (0); PolyPhen benign (0.023); catalogued as COSV100237747; called by muse, mutect2, varscan2
- SYNE1 | c.14893C>G p.H4965D (on ENST00000367255 / NM_182961.4; = p.H4894D on NM_033071.3) | Missense Mutation (SNP) | VAF 55/136 reads (40%) | SIFT tolerated (0.58); PolyPhen benign (0.003); catalogued as COSV99559875; called by muse, mutect2, varscan2
- SYNE2 | c.3256A>G p.T1086A | Missense Mutation (SNP) | VAF 18/67 reads (27%) | SIFT tolerated (0.5); PolyPhen benign (0); catalogued as rs549119215, COSV100647349; called by muse, mutect2, varscan2
- TAC1 | c.65T>C p.I22T | Missense Mutation (SNP) | VAF 115/171 reads (67%) | SIFT tolerated (0.22); PolyPhen benign (0.003); catalogued as COSV100071084; called by muse, mutect2, varscan2
- TBX19 | c.682G>C p.V228L | Missense Mutation (SNP) | VAF 13/39 reads (33%) | SIFT tolerated (0.58); PolyPhen benign (0.007); catalogued as COSV100892344; called by muse, mutect2
- TBX22 | c.391G>T p.G131W | Missense Mutation (SNP) | VAF 47/72 reads (65%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100960723; called by muse, mutect2, varscan2
- TCAF2 | c.2258G>T p.W753L | Missense Mutation (SNP) | VAF 17/32 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100633580; called by muse, mutect2, varscan2
- TEDDM1 | c.458T>G p.M153R | Missense Mutation (SNP) | VAF 17/60 reads (28%) | SIFT tolerated (0.5); PolyPhen benign (0.173); catalogued as COSV100842939; called by muse, mutect2, varscan2
- TENM1 | c.6110C>T p.A2037V | Missense Mutation (SNP) | VAF 27/42 reads (64%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.71); catalogued as COSV100948697; called by muse, mutect2, varscan2
- TEX47 | c.480T>A p.D160E | Missense Mutation (SNP) | VAF 45/82 reads (55%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.999); catalogued as COSV99787241; called by muse, mutect2, varscan2
- TKFC | c.177T>G p.H59Q | Missense Mutation (SNP) | VAF 25/62 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100074479; called by muse, mutect2, varscan2
- TM4SF18 | c.52G>T p.A18S | Missense Mutation (SNP) | VAF 13/55 reads (24%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.91); catalogued as COSV99937881; called by muse, mutect2, varscan2
- TMED7-TICAM2 | c.970A>T p.T324S | Missense Mutation (SNP) | VAF 41/59 reads (69%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0.029); catalogued as COSV99143268; called by muse, mutect2, varscan2
- TMEM204 | c.406G>T p.E136* | Nonsense Mutation (SNP) | VAF 16/39 reads (41%) | catalogued as COSV99559853; called by muse, mutect2, varscan2
- TNR | c.3264T>A p.D1088E | Missense Mutation (SNP) | VAF 35/131 reads (27%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.765); catalogued as COSV99688877; called by muse, mutect2, varscan2
- TOGARAM1 | c.4975G>T p.G1659* | Nonsense Mutation (SNP) | VAF 18/56 reads (32%) | catalogued as COSV100817968; called by muse, mutect2, varscan2
- TOX2 | c.644C>A p.S215Y (on ENST00000358131 / NM_001098798.2; = p.S164Y on NM_032883.3) | Missense Mutation (SNP) | VAF 28/100 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100363703; called by muse, mutect2, varscan2
- TRADD | c.469G>A p.D157N | Missense Mutation (SNP) | VAF 7/35 reads (20%) | SIFT tolerated (0.12); PolyPhen benign (0.003); catalogued as rs776567408, COSV99263473; called by muse, mutect2, varscan2
- TRIM36 | c.935A>T p.E312V | Missense Mutation (SNP) | VAF 42/58 reads (72%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.898); catalogued as COSV99142325; called by muse, mutect2, varscan2
- TRIOBP | c.1576C>T p.P526S | Missense Mutation (SNP) | VAF 49/338 reads (14%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.007); catalogued as COSV100730784; called by muse, varscan2
- TSPAN11 | c.721A>T p.T241S | Missense Mutation (SNP) | VAF 34/115 reads (30%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.68); catalogued as COSV99666820; called by muse, mutect2, varscan2
- TSPEAR | c.598G>A p.V200I | Missense Mutation (SNP) | VAF 18/66 reads (27%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs782081048, COSV100552825; called by muse, mutect2, varscan2
- TTN | c.26302C>G p.Q8768E (on ENST00000591111; = p.Q7841E on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 12/46 reads (26%) | PolyPhen benign (0); catalogued as COSV100605001; called by muse, mutect2, varscan2
- TTN | c.11868G>C p.E3956D (on ENST00000591111; = p.E3910D on NM_003319.4) | Missense Mutation (SNP) | VAF 6/23 reads (26%) | catalogued as COSV100605002; called by muse, mutect2, varscan2
- TUBB6 | c.721C>T p.R241C | Missense Mutation (SNP) | VAF 61/105 reads (58%) | SIFT deleterious, low confidence (0.03); PolyPhen probably damaging (0.997); catalogued as rs1446762764, COSV52313188; called by muse, mutect2, varscan2
- TXNDC16 | c.1991G>C p.C664S | Missense Mutation (SNP) | VAF 4/23 reads (17%) | SIFT tolerated (0.11); PolyPhen benign (0.136); catalogued as COSV99909079; called by muse, mutect2
- UBE3A | c.712G>C p.A238P | Missense Mutation (SNP) | VAF 48/130 reads (37%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.876); catalogued as COSV99217043; called by muse, mutect2, varscan2
- UTP4 | c.2008G>A p.D670N | Missense Mutation (SNP) | VAF 45/125 reads (36%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.946); catalogued as COSV58734381; called by muse, mutect2, varscan2
- VARS1 | c.2390C>T p.P797L | Missense Mutation (SNP) | VAF 22/87 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100791797; called by muse, mutect2, varscan2
- WDR17 | c.2831A>T p.H944L | Missense Mutation (SNP) | VAF 17/26 reads (65%) | SIFT tolerated (0.07); PolyPhen benign (0.069); catalogued as rs1003845693, COSV99707343; called by muse, mutect2, varscan2
- WNK2 | c.735G>T p.M245I | Missense Mutation (SNP) | VAF 10/47 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV99941841; called by muse, mutect2, varscan2
- WWP1 | c.1502G>T p.G501V | Missense Mutation (SNP) | VAF 9/48 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.957); catalogued as COSV99616104; called by muse, mutect2, varscan2
- XIRP2 | c.4844T>C p.L1615P (on ENST00000628543; = p.L1790P on NM_152381.6) | Missense Mutation (SNP) | VAF 48/126 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.915); catalogued as rs779586247, COSV99741312; called by muse, mutect2, varscan2
- XYLT1 | c.365A>T p.D122V | Missense Mutation (SNP) | VAF 13/28 reads (46%) | SIFT tolerated, low confidence (0.21); PolyPhen benign (0.01); catalogued as COSV99761218; called by muse, mutect2, varscan2
- ZFHX3 | c.3028C>T p.Q1010* | Nonsense Mutation (SNP) | VAF 36/80 reads (45%) | catalogued as COSV99196680; called by muse, mutect2, varscan2
- ZFHX4 | c.7747G>A p.D2583N | Missense Mutation (SNP) | VAF 25/51 reads (49%) | SIFT deleterious (0.01); PolyPhen benign (0.12); catalogued as COSV99260802, COSV99261164; called by muse, mutect2, varscan2
- ZFP14 | c.224G>A p.R75K | Missense Mutation (SNP) | VAF 24/86 reads (28%) | SIFT tolerated (0.66); PolyPhen benign (0); catalogued as COSV54201303, COSV99525110; called by muse, mutect2, varscan2
- ZFPM2 | c.2204C>T p.T735I | Missense Mutation (SNP) | VAF 26/49 reads (53%) | SIFT deleterious (0); PolyPhen possibly damaging (0.521); catalogued as COSV101023076, COSV101023148; called by muse, mutect2, varscan2
- ZNF135 | c.1828G>C p.D610H (on ENST00000313434 / NM_001289401.2; = p.D622H on NM_003436.4) | Missense Mutation (SNP) | VAF 21/112 reads (19%) | SIFT deleterious (0.03); PolyPhen benign (0.213); catalogued as rs140244919, COSV99046659; called by muse, mutect2, varscan2
- ZNF184 | c.346A>T p.I116F | Missense Mutation (SNP) | VAF 20/49 reads (41%) | SIFT tolerated (0.26); PolyPhen benign (0.007); catalogued as COSV53004678, COSV99279543; called by muse, mutect2, varscan2
- ZNF19 | c.397C>A p.R133S | Missense Mutation (SNP) | VAF 23/60 reads (38%) | SIFT tolerated (0.86); PolyPhen benign (0); catalogued as COSV99867232; called by muse, mutect2, varscan2
- ZNF277 | c.193G>T p.E65* | Nonsense Mutation (SNP) | VAF 32/58 reads (55%) | catalogued as COSV100702386; called by muse, mutect2, varscan2
- ZNF318 | c.5828A>G p.E1943G | Missense Mutation (SNP) | VAF 30/65 reads (46%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.003); catalogued as COSV100546091; called by muse, mutect2, varscan2
- ZNF385B | c.1085C>A p.T362K | Missense Mutation (SNP) | VAF 21/71 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV100415940; called by muse, mutect2, varscan2
- ZNF385B | c.325C>A p.P109T | Missense Mutation (SNP) | VAF 38/121 reads (31%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.897); catalogued as COSV100415942; called by muse, mutect2, varscan2
- ZNF467 | c.662G>T p.C221F | Missense Mutation (SNP) | VAF 5/12 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100117890; called by muse, mutect2, varscan2
- ZZEF1 | c.2605C>G p.P869A | Missense Mutation (SNP) | VAF 29/86 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV101067700; called by muse, mutect2, varscan2
- ZZZ3 | c.2096T>C p.V699A | Missense Mutation (SNP) | VAF 12/30 reads (40%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.98); catalogued as COSV100890274; called by muse, mutect2, varscan2
- AATF | c.1625A>T p.E542V | Missense Mutation (SNP) | VAF 19/83 reads (23%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.791); called by muse, mutect2, varscan2
- ASTN1 | c.3438del p.V1147Wfs*10 | Frame Shift Del (DEL) | VAF 25/97 reads (26%) | called by mutect2, pindel, varscan2
- B4GALT2 | c.1040_1061del p.L347Sfs*52 | Frame Shift Del (DEL) | VAF 87/322 reads (27%) | called by mutect2, pindel, varscan2
- CAMK2B | c.394del p.V132Sfs*22 | Frame Shift Del (DEL) | VAF 13/61 reads (21%) | called by mutect2, pindel, varscan2
- CPN1 | c.61del p.V21* | Frame Shift Del (DEL) | VAF 15/107 reads (14%) | called by mutect2, pindel, varscan2
- CUL5 | c.968dup p.A324Gfs*8 | Frame Shift Ins (INS) | VAF 14/56 reads (25%) | called by mutect2, pindel, varscan2
- DVL1 | c.516del p.L173Cfs*68 | Frame Shift Del (DEL) | VAF 12/26 reads (46%) | called by mutect2, pindel, varscan2
- EML1 | c.1372dup p.A458Gfs*3 | Frame Shift Ins (INS) | VAF 49/160 reads (31%) | called by mutect2, pindel, varscan2
- F13A1 | c.1059del p.F354Sfs*8 | Frame Shift Del (DEL) | VAF 26/67 reads (39%) | called by mutect2, pindel, varscan2
- FAM234A | c.1596del p.P533Qfs*81 | Frame Shift Del (DEL) | VAF 56/210 reads (27%) | called by mutect2, pindel, varscan2
- HEATR9 | c.928C>A p.Q310K | Missense Mutation (SNP) | VAF 35/134 reads (26%) | SIFT tolerated (0.2); PolyPhen benign (0.175); called by muse, mutect2, varscan2
- IGHV4-31 | c.113C>A p.S38Y | Missense Mutation (SNP) | VAF 24/86 reads (28%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.417); called by muse, mutect2
- MAGEB6B | c.1043G>A p.C348Y | Missense Mutation (SNP) | VAF 51/94 reads (54%) | SIFT tolerated (0.34); PolyPhen benign (0); called by muse, mutect2, varscan2
- MLLT6 | c.265G>C p.A89P | Missense Mutation (SNP) | VAF 13/40 reads (33%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.919); called by muse, mutect2, varscan2
- NBPF9 | c.698A>C p.E233A | Missense Mutation (SNP) | VAF 19/60 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); called by mutect2, varscan2
- PHTF1 | c.1864dup p.S622Ffs*15 | Frame Shift Ins (INS) | VAF 14/46 reads (30%) | called by mutect2, pindel, varscan2
- RBP3 | c.3145A>G p.M1049V | Missense Mutation (SNP) | VAF 110/200 reads (55%) | SIFT tolerated (0.3); PolyPhen benign (0.197); called by muse, mutect2, varscan2
- RYR2 | c.6440+1del | Frame Shift Del (DEL) | VAF 16/45 reads (36%) | called by mutect2, pindel, varscan2
- SERPINA5 | c.657dup p.E220Rfs*53 | Frame Shift Ins (INS) | VAF 11/55 reads (20%) | called by mutect2, pindel, varscan2
- SHANK1 | c.5978dup p.L1994Sfs*41 | Frame Shift Ins (INS) | VAF 4/8 reads (50%) | called by mutect2, varscan2
- SYNE1 | c.3976C>T p.R1326C (on ENST00000367255 / NM_182961.4; = p.R1333C on NM_033071.3) | Missense Mutation (SNP) | VAF 39/173 reads (23%) | SIFT deleterious (0.04); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- TCTN3 | c.1811_1812insCTCT p.E605Sfs*10 | Frame Shift Ins (INS) | VAF 32/117 reads (27%) | called by mutect2, pindel, varscan2
- TGFBR2 | c.1412_1422del p.E471Gfs*41 | Frame Shift Del (DEL) | VAF 23/65 reads (35%) | called by mutect2, pindel, varscan2
- UBR5 | c.7207_7230+9del p.X2403_splice | Splice Site (DEL) | VAF 28/202 reads (14%) | called by mutect2, pindel
- XAGE2 | c.227C>G p.T76R | Missense Mutation (SNP) | VAF 74/103 reads (72%) | SIFT tolerated (0.12); PolyPhen benign (0.018); called by muse, mutect2, varscan2
- ZSCAN5B | c.400C>T p.L134F | Missense Mutation (SNP) | VAF 2/14 reads (14%) | SIFT tolerated (0.35); PolyPhen benign (0.003); called by muse, mutect2
- ABCC12 | c.4059A>T p.L1353= | Silent (SNP) | VAF 112/320 reads (35%) | catalogued as COSV100252496; called by muse, mutect2, varscan2
- ACSL5 | c.792C>G p.T264= (on ENST00000354273; = p.T320= on NM_016234.3) | Silent (SNP) | VAF 6/14 reads (43%) | catalogued as COSV100634552; called by muse, mutect2, varscan2
- ADAD2 | c.741G>A p.P247= (on ENST00000315906 / NM_001145400.2; = p.P329= on NM_139174.4) | Silent (SNP) | VAF 17/49 reads (35%) | catalogued as rs374108586; called by muse, mutect2, varscan2
- ADAMTSL4 | c.2880T>C p.P960= | Silent (SNP) | VAF 89/213 reads (42%) | catalogued as rs767138992, COSV99647011; called by muse, mutect2, varscan2
- ALMS1 | c.7848G>T p.R2616= | Silent (SNP) | VAF 20/69 reads (29%) | catalogued as COSV52509976; called by muse, mutect2, varscan2
- ALMS1 | c.8958C>A p.P2986= | Silent (SNP) | VAF 22/77 reads (29%) | catalogued as COSV100041986; called by muse, mutect2, varscan2
- ANKRD27 | c.2109C>T p.V703= | Silent (SNP) | VAF 60/131 reads (46%) | catalogued as rs758973313, COSV100042691; called by muse, mutect2, varscan2
- APOB | c.1584C>A p.I528= | Silent (SNP) | VAF 30/129 reads (23%) | catalogued as rs1456679362, COSV51926068, COSV99264925; called by muse, mutect2, varscan2
- APOH | c.330T>C p.C110= | Silent (SNP) | VAF 8/46 reads (17%) | catalogued as COSV99235696; called by muse, mutect2, varscan2
- ARHGEF17 | c.2601A>G p.V867= | Silent (SNP) | VAF 23/69 reads (33%) | catalogued as COSV99735294; called by muse, mutect2, varscan2
- ASH1L | c.1575A>G p.V525= | Silent (SNP) | VAF 16/50 reads (32%) | catalogued as COSV100853329; called by muse, mutect2, varscan2
- ASTN1 | c.1944C>T p.I648= | Silent (SNP) | VAF 30/90 reads (33%) | catalogued as rs1384820666, COSV99921115; called by muse, mutect2, varscan2
- BEST3 | c.1647C>T p.I549= | Silent (SNP) | VAF 40/102 reads (39%) | catalogued as rs368160228; called by muse, mutect2, varscan2
- CCAR2 | c.1701C>T p.V567= | Silent (SNP) | VAF 32/55 reads (58%) | catalogued as rs1428560693, COSV99373947; called by muse, mutect2, varscan2
- CECR2 | c.2682G>A p.Q894= (on ENST00000342247 / NM_001290047.2; = p.Q711= on NM_001290046.1) | Silent (SNP) | VAF 52/137 reads (38%) | catalogued as COSV52848459, COSV99377596; called by muse, mutect2, varscan2
- CFHR5 | c.1266A>G p.L422= | Silent (SNP) | VAF 10/32 reads (31%) | catalogued as COSV99888401; called by muse, mutect2, varscan2
- CKAP5 | c.5382C>T p.L1794= (on ENST00000529230 / NM_001008938.4; = p.L1734= on NM_014756.3) | Silent (SNP) | VAF 37/96 reads (39%) | catalogued as COSV100370669; called by muse, mutect2, varscan2
- CRB1 | c.2952T>C p.D984= | Silent (SNP) | VAF 28/64 reads (44%) | catalogued as COSV100957799; called by muse, mutect2, varscan2
- CYP11B2 | c.1035G>T p.L345= | Silent (SNP) | VAF 46/131 reads (35%) | catalogued as COSV59997631; called by muse, mutect2, varscan2
- DAB1 | c.1257C>A p.P419= (on ENST00000371231; = p.P386= on NM_021080.5 and 5 other RefSeq transcripts) | Silent (SNP) | VAF 40/127 reads (31%) | catalogued as COSV100976254; called by muse, mutect2, varscan2
- DDX59 | c.1195C>T p.L399= | Silent (SNP) | VAF 45/108 reads (42%) | catalogued as COSV100494498; called by muse, mutect2, varscan2
- DENND2A | c.1173C>A p.R391= | Silent (SNP) | VAF 61/112 reads (54%) | catalogued as COSV52059746, COSV99325944; called by muse, mutect2, varscan2
- DLGAP2 | c.2058G>T p.L686= | Silent (SNP) | VAF 4/12 reads (33%) | catalogued as rs1231635036, COSV101421620; called by muse, mutect2, varscan2
- EML1 | c.2262G>T p.L754= | Silent (SNP) | VAF 32/77 reads (42%) | catalogued as rs754283590, COSV99214814; called by muse, mutect2, varscan2
- ETV6 | c.825C>T p.H275= | Silent (SNP) | VAF 46/160 reads (29%) | catalogued as rs1297782661, COSV101122484; called by muse, mutect2, varscan2
- FAM71B | c.1191C>A p.P397= | Silent (SNP) | VAF 56/74 reads (76%) | catalogued as COSV100262009; called by muse, mutect2, varscan2
- FECH | c.351C>T p.P117= | Silent (SNP) | VAF 31/119 reads (26%) | catalogued as rs572493638, CD075414, COSV100023508; called by muse, mutect2, varscan2
- GABRA6 | c.105C>A p.I35= | Silent (SNP) | VAF 71/107 reads (66%) | catalogued as COSV99194263; called by muse, mutect2, varscan2
- GCOM1 | c.603A>G p.A201= | Silent (SNP) | VAF 26/83 reads (31%) | catalogued as COSV99984813; called by muse, mutect2, varscan2
- GPR149 | c.2142C>A p.I714= | Silent (SNP) | VAF 27/284 reads (10%) | catalogued as COSV101078327, COSV67666766; called by muse, mutect2, varscan2
- HOXA10 | c.372T>A p.S124= | Silent (SNP) | VAF 4/13 reads (31%) | catalogued as COSV99385389; called by muse, mutect2
- IGF1R | c.1668C>G p.L556= | Silent (SNP) | VAF 30/82 reads (37%) | catalogued as rs775291694, COSV99151086, COSV99163486; called by muse, mutect2, varscan2
- IGHV3-16 | c.81G>T p.G27= | Silent (SNP) | VAF 95/321 reads (30%) | called by muse, mutect2, varscan2
- IL10 | c.375C>T p.R125= | Silent (SNP) | VAF 35/94 reads (37%) | catalogued as rs755403362, COSV100894742; called by muse, mutect2, varscan2
- JUNB | c.688C>T p.L230= | Silent (SNP) | VAF 6/16 reads (38%) | catalogued as COSV100040160; called by muse, mutect2, varscan2
- KCNMB1 | c.570G>A p.Q190= | Silent (SNP) | VAF 155/226 reads (69%) | catalogued as COSV99210692; called by muse, mutect2, varscan2
- KCNN3 | c.987C>A p.I329= | Silent (SNP) | VAF 23/58 reads (40%) | catalogued as COSV99678084; called by muse, mutect2, varscan2
- KDM4D | c.681C>T p.A227= | Silent (SNP) | VAF 20/58 reads (34%) | catalogued as COSV100624208, COSV58635891; called by muse, mutect2, varscan2
- LGALS3BP | c.954G>A p.E318= | Silent (SNP) | VAF 11/82 reads (13%) | catalogued as COSV99431571; called by muse, mutect2, varscan2
- LRRC8D | c.1962T>A p.I654= | Silent (SNP) | VAF 21/53 reads (40%) | catalogued as COSV100487174, COSV61577675; called by muse, mutect2, varscan2
- MAGEC3 | c.1863C>A p.T621= | Silent (SNP) | VAF 81/94 reads (86%) | catalogued as COSV100024716; called by muse, mutect2, varscan2
- MAP2 | c.1368G>T p.V456= | Silent (SNP) | VAF 10/32 reads (31%) | catalogued as COSV99559170; called by muse, varscan2
- MAP3K10 | c.1659G>A p.K553= | Silent (SNP) | VAF 13/40 reads (33%) | catalogued as rs750140605, COSV99454221; called by muse, mutect2, varscan2
- MMS19 | c.1356A>G p.L452= | Silent (SNP) | VAF 89/191 reads (47%) | catalogued as rs770533509, COSV100512767; called by muse, mutect2, varscan2
- MUC4 | c.2286C>T p.T762= | Silent (SNP) | VAF 39/123 reads (32%) | catalogued as rs1441762039, COSV100640250; called by muse, mutect2, varscan2
- MUC5B | c.12294C>A p.A4098= | Silent (SNP) | VAF 88/314 reads (28%) | catalogued as COSV101500231; called by muse, mutect2, varscan2
- MYH1 | c.1764C>G p.T588= | Silent (SNP) | VAF 26/86 reads (30%) | catalogued as COSV56856351, COSV99875540; called by muse, mutect2, varscan2
- MYOCD | c.2364C>T p.A788= | Silent (SNP) | VAF 24/88 reads (27%) | catalogued as rs751877797, COSV100590572; called by muse, mutect2, varscan2
- NCAM2 | c.525C>T p.N175= | Silent (SNP) | VAF 14/49 reads (29%) | catalogued as rs779423340, COSV99522499; called by muse, mutect2, varscan2
- NPY2R | c.261T>C p.F87= | Silent (SNP) | VAF 30/60 reads (50%) | catalogued as COSV100279608; called by muse, mutect2, varscan2
- NR4A1 | c.621G>A p.L207= | Silent (SNP) | VAF 63/298 reads (21%) | catalogued as rs140048797; called by muse, mutect2, varscan2
- NSMCE1 | c.630G>A p.R210= | Silent (SNP) | VAF 21/76 reads (28%) | catalogued as COSV99619461; called by muse, mutect2, varscan2
- NXPE4 | c.1257C>A p.A419= (on ENST00000375478 / NM_001077639.2; = p.A135= on NM_017678.3) | Silent (SNP) | VAF 70/202 reads (35%) | catalogued as COSV64944547; called by muse, mutect2, varscan2
- OBSCN | c.15358C>T p.L5120= | Silent (SNP) | VAF 27/73 reads (37%) | catalogued as rs768530220, COSV99476144; called by muse, mutect2, varscan2
- OR13H1 | c.789C>A p.S263= | Silent (SNP) | VAF 47/79 reads (59%) | catalogued as COSV100088204; called by muse, mutect2, varscan2
- OR1C1 | c.141G>T p.A47= | Silent (SNP) | VAF 11/33 reads (33%) | catalogued as COSV101376230, COSV68715440, COSV68715730; called by muse, mutect2, varscan2
- OR51E1 | c.411A>G p.T137= | Silent (SNP) | VAF 22/109 reads (20%) | catalogued as COSV101211483; called by muse, mutect2, varscan2
- OR8H3 | c.144G>A p.L48= | Silent (SNP) | VAF 84/325 reads (26%) | catalogued as COSV100538872; called by muse, varscan2
- PANK1 | c.54G>C p.A18= | Silent (SNP) | VAF 10/60 reads (17%) | catalogued as rs1299617540, COSV56809019; called by muse, varscan2
- PAPPA | c.918C>G p.P306= | Silent (SNP) | VAF 60/130 reads (46%) | catalogued as COSV100073623; called by muse, mutect2, varscan2
- PCDHGA4 | c.2004G>C p.A668= | Silent (SNP) | VAF 30/46 reads (65%) | catalogued as COSV54038791, COSV99535407; called by muse, mutect2, varscan2
- PDZD3 | c.1086G>A p.P362= (on ENST00000531114; = p.P282= on NM_024791.4) | Silent (SNP) | VAF 51/165 reads (31%) | catalogued as rs759230054, COSV99424087; called by muse, mutect2, varscan2
- PEG3 | c.3033C>A p.A1011= | Silent (SNP) | VAF 12/29 reads (41%) | catalogued as COSV99688361; called by muse, mutect2, varscan2
- PPFIBP2 | c.1557G>T p.T519= | Silent (SNP) | VAF 33/77 reads (43%) | catalogued as rs189054097, COSV100206369; called by muse, mutect2, varscan2
- PRR5L | c.1032C>T p.D344= | Silent (SNP) | VAF 51/154 reads (33%) | catalogued as COSV100286972; called by muse, mutect2, varscan2
- PSD3 | c.735G>A p.E245= | Silent (SNP) | VAF 22/49 reads (45%) | catalogued as COSV100495796; called by muse, mutect2, varscan2
- PSMA4 | c.600C>T p.T200= | Silent (SNP) | VAF 13/60 reads (22%) | catalogued as rs750046972, COSV99245489; called by muse, mutect2, varscan2
- PSME1 | c.186C>T p.D62= | Silent (SNP) | VAF 41/155 reads (26%) | catalogued as COSV99246159; called by muse, mutect2, varscan2
- PTPN11 | c.1029G>T p.R343= | Silent (SNP) | VAF 23/60 reads (38%) | catalogued as COSV100692474, COSV100692827; called by muse, mutect2, varscan2
- RNASEL | c.306G>A p.A102= | Silent (SNP) | VAF 8/35 reads (23%) | catalogued as rs200161417, COSV62376365; called by muse, mutect2, varscan2
- RNASET2 | c.702G>A p.E234= | Silent (SNP) | VAF 89/368 reads (24%) | catalogued as rs1261487980, COSV99218532; called by muse, mutect2, varscan2
- RNF43 | c.1233C>T p.P411= | Silent (SNP) | VAF 8/32 reads (25%) | catalogued as COSV101348372; called by muse, mutect2
- SASH1 | c.891G>T p.S297= | Silent (SNP) | VAF 10/53 reads (19%) | catalogued as COSV100821124; called by muse, mutect2, varscan2
- SLC18A3 | c.759C>A p.L253= | Silent (SNP) | VAF 20/50 reads (40%) | catalogued as COSV100339998; called by muse, mutect2, varscan2
- SLC44A4 | c.318C>T p.N106= | Silent (SNP) | VAF 119/348 reads (34%) | catalogued as rs758008624, COSV99998844; called by muse, mutect2, varscan2
- SLC4A4 | c.1242G>A p.Q414= (on ENST00000264485 / NM_001098484.3; = p.Q370= on NM_003759.4) | Silent (SNP) | VAF 11/60 reads (18%) | catalogued as COSV99138800; called by muse, mutect2, varscan2
- SLCO1B3-SLCO1B7 | c.2151C>A p.T717= (on ENST00000540229 / NM_001371097.1; = p.T656= on NM_001009562.4) | Silent (SNP) | VAF 6/16 reads (38%) | catalogued as COSV101043497; called by muse, mutect2, varscan2
- SPART | c.1770G>T p.A590= | Silent (SNP) | VAF 16/30 reads (53%) | catalogued as COSV100768662; called by muse, mutect2, varscan2
- SPTBN1 | c.3477G>A p.E1159= | Silent (SNP) | VAF 48/133 reads (36%) | catalogued as rs1181679996, COSV100442307; called by muse, mutect2, varscan2
- STON2 | c.6G>T p.T2= | Silent (SNP) | VAF 21/47 reads (45%) | catalogued as COSV50844736, COSV99964626; called by muse, mutect2, varscan2
- SYNE1 | c.17493G>T p.L5831= (on ENST00000367255 / NM_182961.4; = p.L5760= on NM_033071.3) | Silent (SNP) | VAF 12/22 reads (55%) | catalogued as COSV99550908; called by muse, mutect2, varscan2
- TAF1C | c.462C>T p.L154= | Silent (SNP) | VAF 54/163 reads (33%) | catalogued as rs777007515, COSV58984819; called by muse, mutect2, varscan2
- TANC2 | c.2091C>T p.T697= | Silent (SNP) | VAF 21/79 reads (27%) | catalogued as COSV67335924; called by muse, mutect2, varscan2
- TBC1D9 | c.1653G>T p.G551= | Silent (SNP) | VAF 16/200 reads (8%) | catalogued as COSV101464318; called by muse, mutect2
- TEX2 | c.1350G>T p.A450= | Silent (SNP) | VAF 24/163 reads (15%) | catalogued as COSV99366971; called by muse, mutect2, varscan2
- THSD7A | c.750G>A p.E250= | Silent (SNP) | VAF 14/37 reads (38%) | catalogued as COSV101448627; called by muse, mutect2, varscan2
- TPR | c.5571G>A p.K1857= | Silent (SNP) | VAF 21/85 reads (25%) | catalogued as COSV100823809; called by muse, mutect2, varscan2
- TRAV8-3 | c.72C>A p.T24= | Silent (SNP) | VAF 6/30 reads (20%) | called by muse, mutect2, varscan2
- TRIM60 | c.1389C>A p.I463= | Silent (SNP) | VAF 5/14 reads (36%) | catalogued as COSV100593982; called by muse, mutect2, varscan2
- UGT1A8 | c.321T>C p.S107= | Silent (SNP) | VAF 15/87 reads (17%) | catalogued as COSV100990535; called by muse, mutect2, varscan2
- UTP18 | c.705C>T p.I235= | Silent (SNP) | VAF 8/64 reads (13%) | catalogued as rs1302315019, COSV99834693; called by muse, mutect2, varscan2
- ZFHX4 | c.6753A>T p.P2251= | Silent (SNP) | VAF 7/20 reads (35%) | catalogued as COSV99261162; called by muse, mutect2, varscan2
- ZNF512B | c.33G>A p.R11= | Silent (SNP) | VAF 49/145 reads (34%) | catalogued as COSV53870683; called by muse, mutect2, varscan2
- ZSCAN1 | c.144G>A p.V48= | Silent (SNP) | VAF 7/29 reads (24%) | catalogued as rs1464998460, COSV56608913, COSV99991558; called by muse, mutect2, varscan2
- ZSCAN5B | c.327G>T p.V109= | Silent (SNP) | VAF 8/56 reads (14%) | catalogued as COSV100748407; called by muse, mutect2
- C7orf65 | n.244G>A | RNA (SNP) | VAF 18/46 reads (39%) | called by muse, mutect2, varscan2
- C9orf106 | n.686A>T | RNA (SNP) | VAF 60/137 reads (44%) | called by muse, mutect2, varscan2
- F2R | c.88+281G>T | Intron (SNP) | VAF 8/11 reads (73%) | catalogued as COSV100058414; called by muse, mutect2, varscan2
- HERC2P3 | n.1526C>A | RNA (SNP) | VAF 42/201 reads (21%) | called by muse, mutect2, varscan2
- HERC2P3 | n.1153C>G | RNA (SNP) | VAF 19/70 reads (27%) | called by muse, mutect2, varscan2
- NCAM1 | c.1826-5580G>T | Intron (SNP) | VAF 57/189 reads (30%) | catalogued as COSV100377434; called by muse, mutect2, varscan2
